Gene-level copy-number profile of tumor specimen CDDP-ACRK-TTP1-A from CDDP_EAGLE case CDDP-ACRK, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70 years.
Specimen CDDP-ACRK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41aea330-9b4c-424c-ae11-082e97cc5011.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACRK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,295 have no estimate.
https://portal.gdc.cancer.gov/files/5e0fdd85-5737-4495-8cef-8be4ac7f0eed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 20,308; copy number 2: 32,937; copy number 3: 4,716; copy number 4: 230; copy number 5: 42; copy number 6: 8; copy number 7: 2; copy number 13: 1; copy number 19: 18; copy number 20: 2; copy number 23: 2; copy number 24: 4; copy number 25: 41.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,316,324–16,319,566, 1 gene: AC010745.4.
- chr4:10,167,159–10,238,235, 3 genes: AC006499.6, AC006499.1, AC006499.8.
- chr4:189,659,605–189,661,486, 1 gene: LINC01262.
- chr5:795,606–850,986, 2 genes (within-gene range 0–2): ZDHHC11, SPCS2P3.
- chr7:37,032–95,683, 3 genes: AC215522.1, AC093627.1, AC093627.6.
- chr7:3,642,815–3,643,784, 1 gene (within-gene range 0–1): AC011284.1.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–1): C9orf163.
- chr11:65,568,482–65,570,423, 1 gene: ZNRD2-AS1.
- chr16:55,728,115–55,750,111, 1 gene: CES1P2.
- chr16:57,999,546–58,021,618, 1 gene (within-gene range 0–1): USB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 120 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,785,720–153,785,821, 1 gene, copy number 6: Y_RNA.
- chr5:70,049,638–70,078,522, 2 genes, copy number 7: SMN2, AC140134.1.
- chr5:70,495,100–70,500,903, 1 gene, copy number 5: AC146944.1.
- chr5:70,751,184–70,795,914, 2 genes, copy number 5: GUSBP16, AC139272.1.
- chr6:15,102,946–15,113,221, 2 genes, copy number 5: AL050335.1, RN7SL332P.
- chr6:17,393,505–18,273,266, 16 genes, copy number 5: CAP2, RPL7P26, SUMO2P13, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA.
- chr6:21,354,411–21,602,383, 6 genes, copy number 5: AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr7:56,940,341–56,944,353, 1 gene, copy number 13: AC069152.1.
- chr7:74,964,705–75,031,528, 1 gene, copy number 6 (within-gene range 4–6): CASTOR2.
- chr7:75,156,639–75,416,787, 20 genes, copy number 19–20 (within-gene range 3–20): NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1.
- chr7:76,389,334–76,409,697, 1 gene, copy number 5 (within-gene range 2–5): SSC4D.
- chr7:100,319,222–100,336,307, 2 genes, copy number 5 (within-gene range 2–5): PMS2P1, Y_RNA.
- chr7:102,456,238–102,473,168, 3 genes, copy number 5 (within-gene range 2–5): ALKBH4, LRWD1, MIR5090.
- chr7:102,537,918–102,592,444, 5 genes, copy number 5 (within-gene range 4–6): POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3.
- chr10:43,417,249–43,422,100, 2 genes, copy number 5: SNORD3J, AL450326.1.
- chr11:9,384,652–9,460,702, 4 genes, copy number 6 (within-gene range 4–6): IPO7, SNORA23, AC132192.1, AC132192.2.
- chr11:47,659,591–47,715,389, 1 gene, copy number 5: AGBL2.
- chr12:121,874,193–121,874,337, 1 gene, copy number 5: AC069503.3.
- chr16:67,644,988–67,657,569, 1 gene, copy number 6 (within-gene range 3–6): CARMIL2.
- chr19:10,289,952–11,197,791, 45 genes, copy number 23–25: ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT, ILF3, QTRT1, DNM2, MIR638, MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1, LDLR, MIR6886, SPC24, KANK2.
- chr19:11,203,628–11,216,168, 2 genes, copy number 24 (within-gene range 4–24): AC011472.1, AC011472.5.
- chr20:34,122,470–34,123,290, 1 gene, copy number 6: RPS2P1.

Autosomal genes at a single copy (total copy number 1): 19,822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
